Somatic mutation profile of tumor specimen 0DAOBR from CCDI case PBBKIL, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 15.6 years (5,704 days).
Specimen 0DAOBR: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9b89eadf-f293-4f5f-abed-fdcfb4781b82.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DAOBS (Solid Tissue; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9f76217c-8746-41d3-9665-16c6fb31327b

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Splice Site 1, Silent 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- POTEA | c.975+2C>T p.X325_splice (on ENST00000519951 / NM_001005365.2; = p.X279_splice on NM_001002920.1) | Splice Site (SNP) | VAF 67/305 reads (22%) | catalogued as rs777050827; called by muse, mutect2, varscan2
- BTBD16 | c.602T>C p.V201A | Missense Mutation (SNP) | VAF 36/468 reads (8%) | SIFT tolerated (0.38); PolyPhen benign (0.121); called by muse, mutect2
- OR4Q2 | c.411G>A p.M137I | Missense Mutation (SNP) | VAF 18/493 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.565); called by muse, mutect2
- PTPRJ | c.2565C>T p.T855= | Silent (SNP) | VAF 23/722 reads (3%) | called by muse, mutect2
- DAAM1 | c.273+80G>A | Intron (SNP) | VAF 50/152 reads (33%) | called by muse, mutect2, varscan2
